CPTAC case C3L-03405 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed9c82fb-ed4d-4254-a078-20a34cf82283

Demographics
Sex at birth: male; Race: white; Year of birth: 1959; Vital status: Dead; Days to death: 87 days; Year of death: 2018; Cause of death: Cardiovascular Disorder, NOS; Country of birth: Russia.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 59.2 years (21,614 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 87 days; Progression or recurrence: no; Days to last follow up: 87 days.
   Pathology details: Greatest tumor dimension: 5.5 cm.

Follow-up (1 entry)
- Days to follow up: 87 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 76 kg; Height: 168 cm; BMI: 26.93.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03405-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 442 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03405-21: Section location: Frontal and temporal lobe; Percent tumor nuclei: 85; Percent necrosis: 15.
- Sample C3L-03405-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
